CGCI case BLGSP-71-19-00107 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ca76ffd1-4bda-470b-8fe9-942926499e4d

Demographics
Sex at birth: female; Race: white; Age at index: 12 years; Vital status: Dead; Days to death: 222 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 12.7 years (4,637 days); Year of diagnosis: 1990; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 222 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Colon; Sites of involvement: Colon, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric; Lymph nodes tested: 1.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 142 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Colon, NOS; Days to recurrence: 142 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 222 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 155 [Blood test normal range upper: 300].

Other clinical attributes
- Day 0: Weight: 51.5 kg; Height: 165 cm; BMI: 18.9.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00107-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Colon; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00107-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-19-00107-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-19-00107-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: diffuse small non-cleaved cell; Extranodal site involvement: 1; Lymph nodes examined: Yes.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 155.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: Colon (previous site); New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
